Somatic mutation profile of tumor specimen TCGA-SR-A6MP-01A (aliquot TCGA-SR-A6MP-01A-11D-A35I-08) from TCGA case TCGA-SR-A6MP, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 30.3 years (11,050 days).
Specimen TCGA-SR-A6MP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 091a3899-47d4-4fb5-99b3-816379d83f29.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SR-A6MP-10A (Blood Derived Normal), aliquot TCGA-SR-A6MP-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e2b016b-a20a-472b-9ee9-61bc1edd55e8

The open-access MAF lists 23 somatic variants for this specimen: 18 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 3, Intron 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAP13 | c.4691A>G p.H1564R | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs555050692; called by muse, mutect2, varscan2
- BPIFB6 | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs371915417, COSV100848545; called by muse, mutect2, varscan2
- EIF4G3 | c.1781C>T p.S594L | Missense Mutation (SNP) | VAF 28/221 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.017); catalogued as rs758643138; called by muse, mutect2, varscan2
- NUGGC | c.1027C>T p.R343W | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs563017713; called by muse, mutect2, varscan2
- RP1L1 | c.3626G>A p.G1209D | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs773704226; called by muse, mutect2, varscan2
- SCRIB | c.2863C>T p.P955S | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.96); PolyPhen benign (0.258); catalogued as rs1554635933, COSV104412483; called by muse, mutect2, varscan2
- SCRIB | c.2099C>T p.S700F | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV57581841; called by muse, mutect2, varscan2
- SCRIB | c.1888C>T p.Q630* | Nonsense Mutation (SNP) | VAF 59/153 reads (39%) | catalogued as COSV57582416; called by muse, mutect2, varscan2
- SCRIB | c.1708C>T p.H570Y | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.874); catalogued as COSV57589257; called by muse, mutect2, varscan2
- SPDL1 | c.1097A>G p.Y366C | Missense Mutation (SNP) | VAF 55/116 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747434860; called by muse, mutect2, varscan2
- TCAP | c.373G>A p.G125S | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1567865271; called by muse, varscan2
- ABCD3 | c.109G>A p.G37S | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2
- DOCK7 | c.2074G>C p.E692Q | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- GPR156 | c.135A>T p.L45F | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- NSD2 | c.824G>T p.W275L | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- NUP98 | c.3494A>G p.E1165G (on ENST00000359171 / NM_001365126.1; = p.E1148G on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- SCRIB | c.2303C>G p.P768R | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCRIB | c.517C>G p.L173V | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- RP1L1 | c.3744G>T p.G1248= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as COSV66761450; called by muse, mutect2, varscan2
- SCRIB | c.1362C>T p.P454= | Silent (SNP) | VAF 59/125 reads (47%) | catalogued as rs1219226673; called by muse, mutect2, varscan2
- TCAP | c.210G>A p.R70= | Silent (SNP) | VAF 9/15 reads (60%) | called by muse, mutect2, varscan2
- GOSR2 | c.282+2949G>A | Intron (SNP) | VAF 43/103 reads (42%) | catalogued as rs1262961585; called by muse, mutect2, varscan2
- SCRIB | c.643-11C>G | Intron (SNP) | VAF 9/15 reads (60%) | catalogued as rs747481853; called by muse, mutect2, varscan2
